Gene-level copy-number profile of tumor specimen TCGA-3C-AALI-01A from TCGA case TCGA-3C-AALI, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 50.8 years (18,538 days).
Specimen TCGA-3C-AALI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.0fa8d96d-b739-4da6-b525-c62cdabee68c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3C-AALI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cf11593a-04cd-499f-be94-eb109f8ea6cb

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3,401; copy number 2: 16,169; copy number 3: 19,062; copy number 4: 17,851; copy number 5: 1,915; copy number 6: 347; copy number 7: 96; copy number 8: 136; copy number 9: 154; copy number 10: 29; copy number 11: 99; copy number 12: 79; copy number 13: 8; copy number 17: 11; copy number 18: 356; copy number 23: 46; copy number 26: 3; copy number 29: 33; copy number 33: 2; copy number 34: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3C-AALI-01A-11D-A41E-01): tumor purity 0.64, ploidy 3.05, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,068 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:78,533,176–79,612,300, 10 genes, copy number 7–9 (within-gene range 3–9): AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1.
- chr14:60,396,469–60,515,543, 1 gene, copy number 8 (within-gene range 5–8): C14orf39.
- chr14:60,493,766–61,083,733, 17 genes, copy number 8: SALL4P7, SIX6, AL049874.3, AL049874.4, AL049874.2, AL049874.1, SALRNA1, SIX1, SIX4, MNAT1, MAD2L1P1, AL160236.2, SRMP2, TRMT5, AL160236.1, RNU6-398P, SLC38A6.
- chr15:59,049,399–61,229,302, 51 genes, copy number 7–8 (within-gene range 6–8): AC092757.1, CCNB2, AC092757.3, AC092757.2, MYO1E, MIR2116, LDHAL6B, RNU4-80P, AC092756.1, RNU6-212P, AC092868.2, FAM81A, NSA2P4, AC092868.1, Y_RNA, AC092754.2, AC092754.1, RNA5SP396, GCNT3, GTF2A2, AC092755.1, BNIP2, PIGHP1, AC092755.2, RPS3AP6, AC092079.2, AC092079.1, NMNAT1P5, FOXB1, MESTP2, AC009654.1, AC037433.1, ANXA2, AC087385.1, AC087385.2, AC087385.3, ICE2, RORA-AS1, RORA, AC107241.1, CYCSP38, AC009560.1, AC009560.3, AC009560.4, AC009560.2, RORA-AS2, RNA5SP397, AC022898.1, AC022898.2, AC012404.1, AC012404.2.
- chr17:26,981,694–27,170,310, 7 genes, copy number 8: AC069061.1, AC069061.2, PDLIM1P3, GTF2IP6, VN1R71P, TUFMP1, AC129926.2.
- chr17:27,746,132–30,117,497, 140 genes, copy number 9 (broad region; genes not listed).
- chr17:30,117,079–30,126,118, 4 genes, copy number 9: hsa-mir-423, MIR423, MIR3184, AC104984.3.
- chr17:33,013,087–34,174,964, 1 gene, copy number 10 (within-gene range 2–10): ASIC2.
- chr17:33,529,787–34,482,148, 28 genes, copy number 10: AA06, AC011824.3, AC011824.2, AC011824.1, AC024614.1, AC024614.2, AC024614.3, AC024614.4, AC024610.2, AC004147.4, AC024610.1, AC123769.1, TLK2P1, AC004147.1, AC004147.5, RNA5SP438, AC004147.3, AC004147.2, LINC01989, AC005549.1, CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1, AC011193.1.
- chr17:35,808,489–36,110,447, 26 genes, copy number 12: AC015849.2, AC015849.3, AC015849.4, HEATR9, AC015849.6, AC015849.1, CCL5, 7SK, AC015849.5, LRRC37A9P, RDM1, LYZL6, AC244100.1, CCL16, CCL14, AC244100.2, CCL15-CCL14, CCL15, AC244100.3, AC244100.4, CCL23, CCL18, AC243829.4, CCL3, CCL4, RN7SL301P.
- chr17:36,591,879–38,921,770, 76 genes, copy number 8–18 (within-gene range 2–18) (broad region; genes not listed).
- chr17:39,057,019–40,017,813, 39 genes, copy number 11–29: RDM1P5, PLXDC1, AC091178.2, ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3.
- chr17:44,395,281–44,503,430, 1 gene, copy number 7 (within-gene range 1–7): GPATCH8.
- chr17:44,486,153–44,752,264, 12 genes, copy number 7: AC103703.1, FZD2, AC091152.3, SMCO4P1, LINC01180, MEIOC, CCDC43, AC091152.2, AC091152.4, DBF4B, RN7SL819P, AC091152.1.
- chr17:47,891,229–60,422,470, 370 genes, copy number 7–33 (within-gene range 2–33) (broad region; genes not listed).
- chr17:62,343,941–68,601,367, 197 genes, copy number 8–34 (within-gene range 6–34) (broad region; genes not listed).
- chr20:62,877,738–64,313,132, 88 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,949. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
